Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5085, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5085-01A (Primary Tumor).

FINAL DIAGNOSIS

KIDNEY, LEFT, RADICAL NEPHRECTOMY:

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR) CELL TYPE
- B. FUHRMAN'S NUCLEAR GRADE IS 3 OF 4
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 6.8 CM.
- D. THE NEOPLASM EXTENDS THROUGH THE RENAL CAPSULE, BUT IS CONFINED WITHIN GEROTA'S FASCIA.
- E. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- F. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- G. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- H. TNM STAGE: pT3a NX MX.
- I. TNM HISTOLOGIC GRADE = G3.

Source: NCI Genomic Data Commons file e350d010-e6a6-48af-9042-9b59d1cd573a (TCGA-B0-5085.0DC305C0-A6D9-4CDF-8DFC-4D0740ABBDB1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).